Somatic mutation profile of tumor specimen TCGA-66-2734-01A (aliquot TCGA-66-2734-01A-01D-0983-08) from TCGA case TCGA-66-2734, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 62.7 years (22,919 days).
Specimen TCGA-66-2734-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15d6f32d-e7be-4ee6-83f0-7feb9b43f090.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-66-2734-11A (Solid Tissue Normal), aliquot TCGA-66-2734-11A-01D-0983-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c2d4549-f92f-403b-8dd6-17b77fcd8be5

The open-access MAF lists 205 somatic variants for this specimen: 166 protein-altering or splice-affecting, 37 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 142, Silent 37, Nonsense Mutation 10, Frame Shift Del 6, Splice Site 5, Splice Region 2, 3'UTR 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL4A4 | c.4082-1G>T p.X1361_splice | Splice Site (SNP) | VAF 12/88 reads (14%) | catalogued as rs1559438651, COSV99052149; ClinVar: pathogenic; called by mutect2, varscan2
- PTPN11 | c.1508G>T p.G503V | Missense Mutation (SNP) | VAF 37/227 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397507546, CM086897, CM115675, CM1314033, COSV61004973, COSV61005158, COSV61008174; ClinVar: other / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 14/46 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28934571, COSV52661594, COSV52668882, COSV52827572; ClinVar: pathogenic / likely pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- ADCY1 | c.2134T>A p.S712T | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV52034357, COSV52036223; called by muse, mutect2, varscan2
- ADGRG2 | c.2765A>T p.Q922L (on ENST00000379869 / NM_001079858.3; = p.Q919L on NM_005756.4) | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV61339727; called by muse, mutect2, varscan2
- ADGRG2 | c.2237C>A p.P746Q (on ENST00000379869 / NM_001079858.3; = p.P743Q on NM_005756.4) | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61339734; called by mutect2, varscan2
- ADRB2 | c.874G>A p.V292I | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.116); catalogued as rs375254430; called by mutect2, varscan2
- AFF2 | c.2003G>C p.R668T | Missense Mutation (SNP) | VAF 38/234 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.652); catalogued as COSV53993726, COSV53998422; called by muse, mutect2, varscan2
- AKAP4 | c.1349C>A p.S450Y | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.697); catalogued as COSV62074696; called by mutect2, varscan2
- ARFGEF1 | c.790G>T p.D264Y | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV51610633; called by mutect2, varscan2
- ARSF | c.935G>T p.G312V | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100839499, COSV100839501; called by mutect2, varscan2
- ASCL3 | c.270C>A p.Y90* | Nonsense Mutation (SNP) | VAF 24/122 reads (20%) | catalogued as COSV57941022, COSV57941155, COSV57941437; called by muse, mutect2, varscan2
- ASH1L | c.3800G>T p.R1267M | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV64209259; called by muse, mutect2, varscan2
- ASXL1 | c.160G>T p.A54S | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867857427, COSV60110712, COSV60116625; called by mutect2, varscan2
- ATP1A3 | c.1330C>A p.P444T (on ENST00000545399 / NM_001256214.2; = p.P431T on NM_152296.5) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as COSV57488375, COSV57489031; called by mutect2, varscan2
- ATXN3 | c.753G>T p.R251S | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.1); catalogued as COSV61495901; called by mutect2, varscan2
- BACH2 | c.43G>C p.E15Q | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57596413; called by muse, mutect2, varscan2
- BCLAF1 | c.1631G>A p.R544H | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs368236501; called by mutect2, varscan2
- C2 | c.820A>G p.K274E | Missense Mutation (SNP) | VAF 39/239 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV54961051; called by muse, mutect2, varscan2
- C8B | c.1175T>A p.V392D | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.915); catalogued as COSV64778128; called by muse, mutect2, varscan2
- CA10 | c.272G>T p.G91V | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV53354882; called by muse, mutect2, varscan2
- CA11 | c.641-2A>C p.X214_splice | Splice Site (SNP) | VAF 15/120 reads (13%) | catalogued as COSV99320625; called by muse, mutect2, varscan2
- CASZ1 | c.1582C>T p.R528C | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59737022; called by mutect2, varscan2
- CCDC80 | c.935A>T p.K312I | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV52817628; called by muse, mutect2, varscan2
- CDS1 | c.140A>G p.Y47C | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.428); catalogued as rs775124128, COSV55688526; called by muse, mutect2, varscan2
- CHM | c.588G>T p.M196I | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV63302481; called by mutect2, varscan2
- CLMN | c.1824G>T p.R608S | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.165); catalogued as COSV54183422; called by muse, mutect2, varscan2
- CLRN3 | c.583G>T p.V195L | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.02); catalogued as COSV64098741; called by muse, mutect2, varscan2
- COL6A3 | c.6393del p.N2132Ifs*110 | Frame Shift Del (DEL) | VAF 50/330 reads (15%) | catalogued as COSV99798328; called by mutect2, pindel, varscan2
- CRISPLD1 | c.1431G>T p.Q477H | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV51544084, COSV51549453; called by mutect2, varscan2
- CYP4F12 | c.695T>A p.V232E | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV61174388; called by muse, mutect2, varscan2
- DDX4 | c.439A>G p.R147G | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.977); catalogued as COSV61755507; called by muse, mutect2
- DDX46 | c.2749G>T p.E917* | Nonsense Mutation (SNP) | VAF 8/62 reads (13%) | catalogued as COSV62799656; called by mutect2, varscan2
- DGKA | c.127G>A p.V43I | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1218011738, COSV59386576; called by mutect2, varscan2
- DNAH5 | c.12458C>A p.P4153H | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776662130, COSV54232468; called by muse, mutect2, varscan2
- DNAH5 | c.12457C>A p.P4153T | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54232481; called by muse, mutect2, varscan2
- DPY19L2 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.148); catalogued as rs111719532, COSV60543982; called by muse, mutect2, varscan2
- DPY19L3 | c.319C>T p.L107F | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.9); PolyPhen benign (0.013); catalogued as COSV60477639; called by muse, mutect2
- DSG3 | c.1286G>A p.R429H | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.049); catalogued as rs200258412, COSV57125955; called by mutect2, varscan2
- DZIP3 | c.2108A>T p.K703I | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as COSV64312506; called by muse, mutect2, varscan2
- EDEM1 | c.1483G>T p.V495L | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV56582338; called by muse, mutect2, varscan2
- ELAVL3 | c.812C>A p.A271E | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.206); catalogued as rs144639070; called by muse, mutect2, varscan2
- EMILIN2 | c.1969C>A p.P657T | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as COSV54424639; called by muse, mutect2, varscan2
- FAT4 | c.4868G>T p.G1623V | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as COSV67889562; called by muse, mutect2, varscan2
- FBXW10 | c.3038T>C p.V1013A | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as rs373632534; called by muse, mutect2, varscan2
- FLG | c.1451G>C p.R484P | Missense Mutation (SNP) | VAF 43/257 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.896); catalogued as COSV64243153; called by muse, mutect2, varscan2
- FLNA | c.3568A>G p.S1190G | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as COSV61045244; called by muse, mutect2, varscan2
- FRMPD3 | c.4931G>T p.S1644I | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as COSV99346285; called by mutect2, varscan2
- GABRG3 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.103); catalogued as COSV61520594, COSV61521127; called by muse, mutect2, varscan2
- GFPT2 | c.534+1G>T p.X178_splice | Splice Site (SNP) | VAF 15/98 reads (15%) | catalogued as COSV53809394; called by muse, mutect2, varscan2
- GFPT2 | c.534G>T p.L178F | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV53809402; called by muse, mutect2, varscan2
- GLI2 | c.1699C>A p.H567N (on ENST00000361492 / NM_001374353.1; = p.H584N on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/251 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58044266; called by muse, mutect2
- GPR50 | c.70C>A p.P24T | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as COSV54439874; called by mutect2, varscan2
- GRAMD1B | c.1913T>C p.L638P | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59205851, COSV59206082; called by muse, mutect2
- GYG2 | c.1304C>A p.A435D | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.074); catalogued as COSV58549081; called by muse, mutect2, varscan2
- GZMA | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV57112168; called by muse, mutect2, varscan2
- HIVEP3 | c.2365G>C p.E789Q | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as COSV56017157; called by muse, mutect2, varscan2
- HOXA7 | c.476G>T p.R159L | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54218127; called by muse, mutect2, varscan2
- IBTK | c.3025+2T>G p.X1009_splice | Splice Site (SNP) | VAF 12/57 reads (21%) | catalogued as COSV60393585; called by muse, mutect2, varscan2
- IFNA16 | c.113T>C p.L38S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.721); catalogued as rs776937108, COSV66510166; called by muse, mutect2, varscan2
- IGHV2-5 | c.286A>G p.K96E | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.351); catalogued as rs1029415357; called by muse, mutect2, varscan2
- INHBB | c.712T>G p.L238V | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.074); catalogued as COSV54678433; called by muse, mutect2
- ISG20 | c.138G>C p.E46D | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV60143972; called by muse, mutect2, varscan2
- ISY1-RAB43 | c.834A>C p.E278D | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.056); catalogued as COSV56441439; called by muse, mutect2, varscan2
- KALRN | c.6274G>T p.E2092* (on ENST00000360013 / NM_001024660.4; = p.E395* on NM_007064.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 13/122 reads (11%) | catalogued as COSV52258599; called by mutect2, varscan2
- KLF8 | c.781C>A p.Q261K | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV63848078, COSV63848821; called by muse, mutect2, varscan2
- KRTAP5-3 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.362); catalogued as COSV68790805; called by muse, varscan2
- LCE3D | c.235G>T p.G79C | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.443); catalogued as COSV64230813; called by mutect2, varscan2
- LILRB4 | c.1265G>T p.R422I (on ENST00000391733 / NM_001278428.3; = p.R421I on NM_001278426.3) | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54406223; called by muse, mutect2
- LMBRD2 | c.1947A>G p.I649M | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.293); catalogued as COSV56950735; called by muse, mutect2, varscan2
- LRRTM1 | c.1159C>T p.P387S | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1279057119, COSV54439609, COSV54443335; called by muse, mutect2, varscan2
- MAGEC1 | c.2279C>A p.P760H | Missense Mutation (SNP) | VAF 35/230 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); catalogued as COSV99595660; called by muse, mutect2, varscan2
- MAGEC2 | c.557G>T p.R186L | Missense Mutation (SNP) | VAF 33/252 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.027); catalogued as rs748643907, COSV55999635, COSV55999836; called by muse, mutect2, varscan2
- MNDA | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV63741115; called by muse, mutect2
- MRGPRX3 | c.82C>A p.L28M | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.15); catalogued as COSV101283532; called by muse, mutect2, varscan2
- MS4A7 | c.556G>T p.V186L | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.018); catalogued as COSV55730159; called by muse, mutect2, varscan2
- MSN | c.1246C>G p.Q416E | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.034); catalogued as COSV64304428; called by muse, mutect2, varscan2
- MTM1 | c.708G>T p.K236N | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV60335548; called by mutect2, varscan2
- MYCBP2 | c.7786G>A p.G2596R (on ENST00000357337; = p.G2634R on NM_015057.5) | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62023889; called by muse, mutect2, varscan2
- MYOC | c.566G>T p.R189L | Missense Mutation (SNP) | VAF 58/242 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV50675587; called by muse, mutect2, varscan2
- NAA25 | c.1783G>T p.E595* | Nonsense Mutation (SNP) | VAF 11/72 reads (15%) | catalogued as COSV55705201; called by muse, mutect2, varscan2
- NIPBL | c.5641A>G p.T1881A | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as rs376084993; called by muse, mutect2, varscan2
- NLGN4X | c.1053C>A p.D351E | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as COSV52008470, COSV52023026; called by muse, mutect2, varscan2
- NOS1 | c.111T>A p.S37R | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.384); catalogued as COSV57614723; called by muse, mutect2, varscan2
- NUP205 | c.1740G>T p.Q580H | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV53660824; called by muse, mutect2, varscan2
- OCRL | c.2657G>C p.R886P | Missense Mutation (SNP) | VAF 37/214 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV63981109; called by muse, mutect2, varscan2
- OR10V1 | c.218A>G p.Y73C | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs371214317; called by mutect2, varscan2
- OR2AG2 | c.853C>G p.L285V | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58455463; called by muse, mutect2, varscan2
- OR5AS1 | c.494G>C p.R165T | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV57982164; called by muse, mutect2
- OR6M1 | c.127A>G p.I43V | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); catalogued as COSV58433957; called by muse, mutect2, varscan2
- OR8B4 | c.84C>A p.F28L | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.076); catalogued as COSV62069967, COSV62070555; called by muse, mutect2, varscan2
- OR8B8 | c.455G>A p.G152E | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV60144881; called by muse, mutect2, varscan2
- OR8I2 | c.722C>A p.A241E | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as COSV56168484; called by muse, mutect2, varscan2
- PDE8B | c.1022G>T p.W341L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV53739278; called by muse, mutect2, varscan2
- PDHA1 | c.606C>A p.G202= | Splice Region (SNP) | VAF 26/183 reads (14%) | catalogued as COSV58826394, COSV58832146; called by muse, mutect2, varscan2
- PDHA2 | c.93C>A p.D31E | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs143281239, COSV54779791; called by muse, varscan2
- PEX2 | c.573G>T p.M191I | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.457); catalogued as COSV63813759; called by muse, mutect2, varscan2
- PHC3 | c.2047A>T p.S683C (on ENST00000494943 / NM_001308116.2; = p.S695C on NM_024947.4) | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.533); catalogued as COSV71948895; called by muse, mutect2, varscan2
- PHGDH | c.161G>C p.R54P | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65571261; called by muse, mutect2, varscan2
- PIK3R4 | c.3957G>T p.R1319S | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV100650237; called by mutect2, varscan2
- PKD1 | c.4603C>T p.R1535C | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.93); catalogued as rs755028574, COSV51917466; called by muse, mutect2, varscan2
- PKHD1 | c.6539C>A p.S2180Y | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV61867414, COSV61881315; called by mutect2, varscan2
- PLD2 | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs1458319184, COSV54006853; called by muse, mutect2, varscan2
- PRB3 | c.326A>T p.Q109L | Missense Mutation (SNP) | VAF 40/266 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV54391016; called by muse, varscan2
- PRDM9 | c.885C>A p.I295= | Splice Region (SNP) | VAF 14/70 reads (20%) | catalogued as COSV57007968, COSV99690319; called by muse, mutect2, varscan2
- PRSS35 | c.1070C>A p.P357Q | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.83); catalogued as COSV63800364, COSV63800739; called by muse, mutect2, varscan2
- PTPRO | c.2988C>A p.N996K (on ENST00000281171 / NM_030667.3; = p.N968K on NM_002848.4) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55512980; called by muse, mutect2, varscan2
- RAG2 | c.496C>A p.H166N | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV100271288; called by muse, mutect2, varscan2
- RALGAPA2 | c.3798G>T p.W1266C | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52500777; called by muse, mutect2, varscan2
- RALGAPA2 | c.3797G>T p.W1266L | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV52500798; called by muse, mutect2, varscan2
- RBMX | c.23G>T p.G8V | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); catalogued as COSV100284859, COSV57809695; called by muse, mutect2, varscan2
- RBMX | c.22G>T p.G8* | Nonsense Mutation (SNP) | VAF 23/144 reads (16%) | catalogued as COSV57809701; called by muse, mutect2, varscan2
- RFPL1 | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.614); catalogued as rs757533010, COSV62978123; called by mutect2, varscan2
- RRBP1 | c.2716G>T p.E906* (on ENST00000377813 / NM_001365613.2; = p.E473* on NM_004587.3) | Nonsense Mutation (SNP) | VAF 10/21 reads (48%) | catalogued as COSV55701993; called by muse, mutect2, varscan2
- RYR2 | c.2610C>A p.S870R | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.812); catalogued as COSV63691639; called by muse, mutect2, varscan2
- RYR2 | c.7705A>T p.I2569L | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV63691647; called by muse, mutect2, varscan2
- RYR3 | c.7755G>T p.L2585F (on ENST00000389232; = p.L2586F on NM_001036.6) | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.614); catalogued as COSV66794940; called by muse, mutect2, varscan2
- SASH1 | c.3026G>T p.G1009V | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as COSV100821186; called by mutect2, varscan2
- SAXO1 | c.1170G>T p.K390N | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65870545; called by muse, mutect2, varscan2
- SCUBE3 | c.2785C>T p.R929* | Nonsense Mutation (SNP) | VAF 27/195 reads (14%) | catalogued as rs1397172310, COSV51457809; called by muse, mutect2, varscan2
- SEMA5B | c.1383G>T p.E461D | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV52100740; called by muse, mutect2, varscan2
- SERPINA7 | c.316G>C p.V106L | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1254254939, COSV59665958, COSV59666149; called by muse, mutect2, varscan2
- SLC26A6 | c.2014A>G p.I672V | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.116); catalogued as COSV56572769; called by muse, mutect2, varscan2
- SOX14 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV60163042; called by muse, mutect2
- SPDEF | c.794A>G p.Y265C | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.148); catalogued as COSV55060748; called by muse, mutect2, varscan2
- STPG4 | c.373C>G p.P125A | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.149); catalogued as COSV54279032; called by muse, mutect2, varscan2
- SYT3 | c.973G>T p.D325Y | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV58897337; called by mutect2, varscan2
- SYTL4 | c.497G>T p.W166L | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as COSV52166061, COSV52168544; called by muse, mutect2, varscan2
- TAB3 | c.533C>A p.P178Q | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV55838017; called by muse, mutect2, varscan2
- TAMALIN | c.317A>T p.K106M | Missense Mutation (SNP) | VAF 32/213 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53336995; called by muse, mutect2, varscan2
- TCF7L2 | c.1146G>T p.Q382H (on ENST00000355995 / NM_001367943.1; = p.Q359H on NM_030756.5) | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV53342426; called by muse, mutect2, varscan2
- THRAP3 | c.1403C>A p.S468* | Nonsense Mutation (SNP) | VAF 14/80 reads (18%) | catalogued as COSV100663680, COSV63568431; called by muse, mutect2, varscan2
- TLN2 | c.3092C>T p.T1031I | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.15); catalogued as COSV60890992; called by muse, mutect2, varscan2
- TLN2 | c.4345G>T p.V1449F | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs1567531382, COSV60890998; called by muse, mutect2, varscan2
- TMC5 | c.1715G>C p.W572S (on ENST00000396229 / NM_001105248.1; = p.W326S on NM_024780.5) | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54905485; called by muse, mutect2, varscan2
- TMC5 | c.1716G>T p.W572C (on ENST00000396229 / NM_001105248.1; = p.W326C on NM_024780.5) | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54905514; called by muse, mutect2, varscan2
- TMED3 | c.250C>T p.Q84* | Nonsense Mutation (SNP) | VAF 20/100 reads (20%) | catalogued as COSV55303040; called by mutect2, varscan2
- TNFAIP3 | c.1831G>A p.G611S | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs756591879, COSV52799683; called by mutect2, varscan2
- TNN | c.1211C>G p.P404R | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV53428484, COSV99513169; called by muse, mutect2, varscan2
- TRIM38 | c.359A>T p.Q120L | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.657); catalogued as COSV62642375; called by muse, mutect2, varscan2
- TRIM58 | c.1084G>T p.V362F | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63570789; called by muse, mutect2, varscan2
- TYRO3 | c.629G>A p.G210D | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1395618928, COSV55484108; called by muse, mutect2, varscan2
- UBR5 | c.4615A>G p.I1539V | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.558); catalogued as COSV55290467; called by muse, mutect2, varscan2
- USP29 | c.2705G>C p.S902T | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.551); catalogued as COSV54143849; called by muse, mutect2, varscan2
- WAS | c.716G>T p.G239V | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64997279; called by muse, mutect2
- XIRP2 | c.517+1G>A p.X173_splice (on ENST00000628543; = p.X348_splice on NM_152381.6) | Splice Site (SNP) | VAF 6/54 reads (11%) | catalogued as rs755784552, COSV54688238, COSV54708903; called by mutect2, varscan2
- YIPF4 | c.538G>C p.V180L | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV53213963; called by muse, mutect2, varscan2
- ZDHHC9 | c.367C>A p.P123T | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64096832; called by muse, mutect2, varscan2
- ZEB1 | c.1454T>A p.L485H | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as COSV58046901; called by muse, mutect2, varscan2
- ZFHX4 | c.7627A>C p.N2543H | Missense Mutation (SNP) | VAF 34/202 reads (17%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.979); catalogued as COSV51441060; called by muse, varscan2
- ZFP42 | c.363A>T p.E121D | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV58817903; called by muse, mutect2, varscan2
- ZNF254 | c.671C>T p.T224I | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.316); catalogued as rs1257383488, COSV61643082; called by mutect2, varscan2
- ZNF280B | c.573G>T p.R191S | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs184628048, COSV64529070; called by mutect2, varscan2
- ZNF284 | c.1174G>T p.V392F | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV69691206; called by muse, mutect2, varscan2
- ZNF491 | c.358A>T p.R120* | Nonsense Mutation (SNP) | VAF 16/78 reads (21%) | catalogued as rs901004820, COSV60057779; called by muse, mutect2, varscan2
- ZNF512B | c.1405G>C p.A469P | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV53872343, COSV53877499; called by muse, mutect2, varscan2
- ZNF782 | c.1862A>G p.N621S | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs768633216, COSV56653231; called by muse, mutect2, varscan2
- ZNF831 | c.3716G>C p.G1239A | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.423); catalogued as COSV64041550; called by muse, mutect2, varscan2
- ADAMTS12 | c.463del p.A155Qfs*9 | Frame Shift Del (DEL) | VAF 8/54 reads (15%) | called by mutect2, pindel, varscan2
- ADGRF1 | c.880del p.V294Sfs*14 | Frame Shift Del (DEL) | VAF 11/68 reads (16%) | called by mutect2, pindel, varscan2
- GDF10 | c.670C>G p.Q224E | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.001); called by mutect2, varscan2
- GRB10 | c.938_939del p.C313Ffs*59 (on ENST00000398812; = p.C255Ffs*59 on NM_001001550.3) | Frame Shift Del (DEL) | VAF 8/66 reads (12%) | called by pindel, varscan2
- IGHG2 | c.347G>A p.G116E | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- KIF16B | c.2966del p.K989Rfs*51 | Frame Shift Del (DEL) | VAF 23/151 reads (15%) | called by mutect2, pindel, varscan2
- RBM12 | c.620del p.P207Qfs*29 | Frame Shift Del (DEL) | VAF 11/75 reads (15%) | called by mutect2, pindel, varscan2
- ZBTB33 | c.1716dup p.H573Sfs*2 | Frame Shift Ins (INS) | VAF 9/47 reads (19%) | called by mutect2, pindel, varscan2
- ACTL8 | c.909C>A p.L303= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as COSV64861704; called by muse, mutect2, varscan2
- BRWD3 | c.714T>C p.A238= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV64749498; called by muse, mutect2, varscan2
- CACNA1I | c.1902C>A p.R634= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV60811205; called by mutect2, varscan2
- CNTNAP2 | c.576C>A p.G192= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV100663473, COSV62198407; called by muse, mutect2, varscan2
- DNAH9 | c.819G>T p.T273= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as COSV52366191; called by muse, varscan2
- DPY19L2 | c.279G>T p.R93= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as COSV60543502; called by muse, mutect2, varscan2
- DSCAML1 | c.4878C>T p.F1626= (on ENST00000321322; = p.F1566= on NM_020693.4) | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as COSV58393999; called by mutect2, varscan2
- DUOX2 | c.909C>T p.P303= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV59908779; called by muse, varscan2
- FAM135B | c.966G>T p.L322= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV52732335, COSV99418870; called by mutect2, varscan2
- FLII | c.3117C>T p.I1039= | Silent (SNP) | VAF 16/140 reads (11%) | catalogued as rs1248529005, COSV57496041; called by muse, mutect2, varscan2
- GPD2 | c.1183C>T p.L395= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV60093563; called by muse, mutect2, varscan2
- HUWE1 | c.5247C>A p.G1749= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV53350447; called by muse, mutect2, varscan2
- IQCF2 | c.81A>C p.T27= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV60761557; called by muse, mutect2, varscan2
- KAAG1 | c.198G>A p.A66= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV51239775; called by muse, mutect2, varscan2
- KIF4A | c.144C>G p.S48= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as COSV53452939; called by muse, mutect2, varscan2
- KIRREL3 | c.738C>A p.I246= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV73106606; called by mutect2, varscan2
- LARGE1 | c.603A>G p.A201= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as COSV61663789; called by muse, mutect2, varscan2
- MAGEE2 | c.897G>T p.L299= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as COSV64897909; called by mutect2, varscan2
- MRM2 | c.468G>T p.A156= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV54248380, COSV54248433; called by muse, mutect2, varscan2
- OR10H2 | c.342G>T p.L114= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV59946240; called by mutect2, varscan2
- PATZ1 | c.267C>T p.G89= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs1413362655, COSV53229762; called by mutect2, varscan2
- PCK1 | c.603T>A p.P201= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV60128969; called by mutect2, varscan2
- PI16 | c.889C>T p.L297= | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as COSV65320792; called by muse, mutect2, varscan2
- PIK3C2B | c.1119G>T p.G373= | Silent (SNP) | VAF 17/99 reads (17%) | catalogued as COSV65803755; called by mutect2, varscan2
- PLXNA3 | c.492G>A p.K164= | Silent (SNP) | VAF 28/131 reads (21%) | catalogued as COSV63754455; called by muse, mutect2, varscan2
- PNRC2 | c.294T>C p.F98= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs1228064126; called by muse, mutect2, varscan2
- RAB6D | c.579G>C p.L193= | Silent (SNP) | VAF 5/40 reads (13%) | called by mutect2, varscan2
- RB1CC1 | c.1581A>G p.L527= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV50253113; called by muse, mutect2, varscan2
- RBM12 | c.1428A>G p.V476= | Silent (SNP) | VAF 35/152 reads (23%) | catalogued as rs1197726161, COSV58292556; called by muse, mutect2, varscan2
- RYR2 | c.2712T>C p.Y904= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as rs758586059, COSV63691643; ClinVar: likely benign; called by muse, mutect2, varscan2
- S100PBP | c.159C>T p.Y53= | Silent (SNP) | VAF 7/69 reads (10%) | catalogued as COSV63140224; called by mutect2, varscan2
- SCN4A | c.1902C>T p.P634= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as rs368811155; ClinVar: conflicting interpretations of pathogenicity / likely benign; called by muse, varscan2
- SLC30A8 | c.987G>A p.V329= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as COSV69971951; called by muse, mutect2, varscan2
- SMR3A | c.249C>G p.P83= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV56950402; called by muse, mutect2, varscan2
- TGIF2LX | c.330G>T p.P110= | Silent (SNP) | VAF 23/144 reads (16%) | catalogued as COSV99383324; called by muse, mutect2, varscan2
- TRIM75P | c.900T>A p.P300= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV72295858; called by muse, mutect2, varscan2
- UNC13C | c.1824A>C p.G608= | Silent (SNP) | VAF 17/89 reads (19%) | catalogued as COSV52885516; called by muse, mutect2, varscan2
- CLRN1 | c.*1083G>A | 3'UTR (SNP) | VAF 8/77 reads (10%) | catalogued as COSV55804640, COSV99902461; called by mutect2, varscan2
- GRB10 | c.-1C>A | 5'UTR (SNP) | VAF 14/74 reads (19%) | catalogued as COSV100240413; called by mutect2, varscan2
